Somatic mutation profile of tumor specimen C3L-06982-55 (aliquot CPT0404410002) from CPTAC case C3L-06982, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 22.7 years (8,279 days).
Specimen C3L-06982-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fee08d1-9ae9-422e-bcfa-8dc32088dc40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06982-50 (Buccal Cell Normal), aliquot CPT0403350001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3054a36-8c25-48a6-b5c4-f7e7e8a05575

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRKD1 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770860312, COSV59570585; called by muse, mutect2, varscan2
- TVP23B | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs748044673; called by muse, mutect2
- SCN4A | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 209/500 reads (42%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHISA6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDC1 | c.319C>T p.L107= | Silent (SNP) | VAF 95/202 reads (47%) | catalogued as COSV54340541; called by muse, mutect2, varscan2
- AFF4 | c.2637+11G>A | Intron (SNP) | VAF 82/178 reads (46%) | catalogued as COSV99534829; called by muse, mutect2
